Gene-level copy-number profile of tumor specimen TCGA-05-4244-01A from TCGA case TCGA-05-4244, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.5 years (25,752 days).
Specimen TCGA-05-4244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e29ae073-4f2d-4159-b64b-8ab0400ce788.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4244-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7861eb1-789a-4bf1-9965-3dac5d23d086

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 635; copy number 2: 4,811; copy number 3: 11,947; copy number 4: 25,461; copy number 5: 2,854; copy number 6: 8,537; copy number 7: 1,814; copy number 8: 362; copy number 9: 3,293; copy number 10: 73; copy number 12: 22; copy number 17: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4244-01A-01D-1877-01): tumor purity 0.44, ploidy 4.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,393 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–246,507,312, 2,470 genes, copy number 9 (within-gene range 1–9) (broad region; genes not listed).
- chr1:246,321,663–247,348,076, 44 genes, copy number 9: SMYD3-IT1, Y_RNA, AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82, AL390728.5, AL390728.1, VN1R17P, VN1R5, Y_RNA, ZNF496, AC104335.1.
- chr5:58,198–44,413,989, 697 genes, copy number 9 (broad region; genes not listed).
- chr7:38,273,587–38,300,322, 5 genes, copy number 17: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr9:29,214,322–31,254,777, 16 genes, copy number 9: AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2.
- chr19:94,062–1,174,268, 73 genes, copy number 10 (broad region; genes not listed).
- chr19:2,977,538–3,538,334, 22 genes, copy number 12 (within-gene range 4–12): TLE6, TLE2, AC005944.1, TLE5, GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1.
- chr20:37,165,774–39,349,392, 66 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 635. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
